Somatic mutation profile of tumor specimen TARGET-10-PARFEH-09A (aliquot TARGET-10-PARFEH-09A-01D) from TARGET case TARGET-10-PARFEH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (806 days).
Specimen TARGET-10-PARFEH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c0670d2-e8f1-4c60-8b6d-4f62a6e689af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFEH-10A (Blood Derived Normal), aliquot TARGET-10-PARFEH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86d2139c-eaca-4fbc-9bee-744b6fd38d1e

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/51 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ITPR3 | c.5720C>T p.T1907M | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277690994, COSV65406512; called by muse, mutect2
- SPEG | c.5213G>A p.R1738Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1366640105; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1544A>T p.E515V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ASH2L | c.915A>G p.G305= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2
- SERPINB11 | c.435G>A p.T145= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs367579501; called by muse, mutect2, varscan2
- SLC35A3 | c.*747A>C | 3'UTR (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- TMEM222 | c.279+199T>C | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
